Gene-level copy-number profile of tumor specimen TCGA-29-1707-01A from TCGA case TCGA-29-1707, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 41.1 years (15,017 days).
Specimen TCGA-29-1707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.6182c67e-8016-470c-a817-322d3c7f37d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1707-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b036387a-dff7-4d71-a4ce-58233cf4f2fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 158; copy number 1: 18,865; copy number 2: 31,324; copy number 3: 6,322; copy number 4: 2,172; copy number 5: 941; copy number 6: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1707-01A-01D-0559-01): tumor purity 0.88, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 158 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:11,598,470–12,642,854, 13 genes (within-gene range 0–1): DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1.
- chr17:12,671,862–12,706,135, 1 gene (within-gene range 0–1): MYOCD-AS1.
- chr17:19,579,943–19,596,058, 1 gene (within-gene range 0–2): SLC47A1P1.
- chr17:19,600,860–22,706,703, 143 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 973 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:181,887,851–182,794,464, 10 genes, copy number 5: AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P, DNAJC10, RPL31P15.
- chr3:30,726,200–31,637,616, 7 genes, copy number 5: GADL1, MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1, STT3B.
- chr7:70,837,738–108,639,349, 737 genes, copy number 5–6 (broad region; genes not listed).
- chr10:44,712–12,965,275, 218 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:12,924,679–12,924,785, 1 gene, copy number 5: RNA5SP300.

Autosomal genes at a single copy (total copy number 1): 18,670. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
